Surgical pathology report (de-identified scan), TCGA case TCGA-XK-AAJU, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-XK-AAJU-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

ADDENDUM PRESENT

Clinic Number: [REDACTED]
Date of Birth: (Age: Gender: M
Requested By:

Accession #:
Procedure Date:
Received Date:
Account #:
Report Signed:

Final Diagnosis:

Prostate with bilateral lymph nodes.

Procedure: Excision and dissection.

Histologic type: Prostatic adenocarcinoma.

Histologic grade:

Primary pattern: 4. Secondary pattern: 3.

Total Gleason Score: 7.

Tumor quantitation: Tumor is present in left and right apex, left and right mid, and left base of prostate. Largest contiguous focus is in the left mid measuring 2 cm.

Extraprostatic extension: Not identified.

Margins: Negative for carcinoma.

Lymph-vascular invasion: Present (block A6).

Perineural invasion: Present.

Seminal vesicle invasion: Not identified.

Treatment effect on carcinoma: Not applicable.

Lymph node sampling: Five lymph nodes with no evidence of metastatic carcinoma identified (0/5).

Additional pathologic findings: Block A17 contains tumor.

Pathologic staging: pT2c, pN0.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 061.9
403/25/14

Interpreted by:

Report electronically signed out by

Transcribed by:

ADDENDA:

Paraffin embedded tumor tissue was sent to
() ; interpreted by () follows:

for DNA ploidy by DIA studies. The report

Ki-67 Antigen immunohistochemical test results are valid for paraffin embedded tissue sections fixed in formalin. Testing is performed using the
MIB-1 clone and a polymer-based detection system. Image collection and analysis is performed using the instrument,
The renders the percentage of positive staining tumor nuclei (tumor selected by operator).

Source: Prostate, radical prostatectomy, block 1 A9

[page 2 of 4]
Results:

The cancer cells are DNA aneuploid.

DIA ploidy test results have been validated by our laboratory for formalin-fixed, paraffin embedded tissue sections. Analysis was performed using the instrument which determined DNA ploidy status by comparing the DNA content of tumor cells and control cells (selected by operator). This test was developed and its performance characteristics determined by the U.S. Food and Drug Administration. This test has not been cleared or approved.

Proliferation index (MIB-1) = 4.04%.

Transcribed by

Signed by:

Clinical Information:

Prostate cancer.

Specimen(s):

A: Prostate with bilateral lymph nodes

Gross Description:

Performed by _____, Pathologist's Assistant

A1A2A3A4A5A6A7A8A9A10A11A12A13A14A15A16A17A18A19A20A21

A. Received fresh labeled _____ and "prostate with bilateral pelvic lymph nodes." Procedure: Radical prostatectomy

Prostate size: Weight: 55 grams; Dimensions: 4.5 x 4 x 3.8 cm; Seminal vesicles: 2 x 1.5 x 1 cm.

Gross notes: Grossly evident tumor: None.
Symmetry: Symmetrical.
Gross nodular hyperplasia: Moderate.
Gross capsular bulge/defect: None.
Inking: left-black, right-blue

Lymph nodes: Pelvic lymph nodes are present in fat aggregating to 5 x 2 x 2 cm. Within the adipose tissue are five grossly identifiable lymph nodes.

Block summary for specimen :

- 1) proximal urethral margin
- 2) distal urethral margin
- 3) left apical margin
- 4) right apical margin
- 5) left bladder neck margin
- 6) right bladder neck margin
- 7) left apical prostate
- 8) right apical prostate
- 9) left mid prostate
- 10) right mid prostate
- 11) left mid prostate

[page 3 of 4]
- 12) right mid prostate
13) left base of prostate
14) right base of prostate
15) left seminal vesicle
16) right seminal vesicle

Additional sections:

- 17) sample corresponding to research,
18) two lymph nodes.
19) one fatty lymph node, bisected.
20) one fatty lymph node, bisected.
21) one fatty lymph node, bisected.

left mid.

*Pw TSS dx discrepancy form,
TCBA tumor is Gleason 4+4.*

Criteria	hw 1/30/14	Yes	No

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by
They have not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is
not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as
qualified to perform high complexity clinical laboratory testing

END OF REPORT

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Issue Source Site (TSS): _____

TSS Identifier: _____

TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____

Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Adeno carcinoma Gleason 4+3=7	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	adenocarcinoma Gleason 4+4=8	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Gleason score is 7 in pathology report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form. Sample is graded higher at 8.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file f6f4839b-959a-482f-8228-665706416783 (TCGA-XK-AAJU.08C5834B-E57D-4182-86DE-4B83314D6799.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).